FM case AD15406 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/ac97c35c-1418-4059-94d2-eadd7d02942e

Female, 64.5 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the breast; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
